Gene-level copy-number profile of tumor specimen TCGA-2G-AAES-01A from TCGA case TCGA-2G-AAES, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 29.7 years (10,848 days).
Specimen TCGA-2G-AAES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d57e3bc9-d0f7-441d-bc94-37ef94e84c99.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAES-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/5e87844c-f6ae-45bf-91af-3bae8ea7dbb3

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 8,557; copy number 1: 35,176; copy number 2: 4,881; copy number 3: 10,303.

Caution: 8,045 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 8,045 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,239,843–196,160,893, 523 genes (broad region; genes not listed).
- chr3:197,298,252–198,123,232, 31 genes (within-gene range 0–1): DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:58,198–181,342,213, 2,901 genes (broad region; genes not listed).
- chr11:86,649–135,075,908, 3,301 genes (broad region; genes not listed).
- chr14:22,185,562–22,552,156, 86 genes (within-gene range 0–1) (broad region; genes not listed).
- chr17:36,110,150–36,177,510, 4 genes (within-gene range 0–1): RN7SL301P, AC243829.2, AC243829.7, TBC1D3B.
- chr18:45,034–80,247,514, 1,199 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 10,303 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,023,918–218,930,636, 1,503 genes, copy number 3 (broad region; genes not listed).
- chr7:4,682,295–56,687,366, 887 genes, copy number 3 (broad region; genes not listed).
- chr7:57,167,200–67,362,950, 242 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:72,558,744–75,738,962, 111 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:75,769,533–142,106,747, 1,137 genes, copy number 3 (broad region; genes not listed).
- chr8:7,355,517–7,385,558, 2 genes, copy number 3: ZNF705G, DEFB108C.
- chr8:12,628,476–61,944,180, 821 genes, copy number 3 (broad region; genes not listed).
- chr8:63,013,068–141,344,621, 1,077 genes, copy number 3 (broad region; genes not listed).
- chr12:66,767–1,660,380, 33 genes, copy number 3: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649.
- chr12:2,695,765–114,767,989, 2,426 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr15:19,878,555–20,003,862, 9 genes, copy number 3: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A.
- chr15:22,258,138–24,090,821, 50 genes, copy number 3: AC025884.2, AC025884.1, AC100757.2, AC100757.1, SPATA31E3P, GOLGA8EP, RN7SL545P, AC100757.3, GOLGA6L22, HERC2P7, HERC2P2, GOLGA8IP, RN7SL495P, WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4.
- chr15:24,162,754–24,225,854, 2 genes, copy number 3: PWRN2, AC087463.1.
- chr15:28,788,243–86,116,747, 1,489 genes, copy number 3 (broad region; genes not listed).
- chr15:86,138,269–86,140,240, 2 genes, copy number 3: RNA5SP400, AC016180.2.
- chr15:101,602,786–101,979,093, 24 genes, copy number 3: LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr21:13,038,160–39,321,559, 488 genes, copy number 3 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 32,832. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
